Somatic mutation profile of tumor specimen C3N-01212-03 (aliquot CPT0075380009) from CPTAC case C3N-01212, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.5 years (23,206 days).
Specimen C3N-01212-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eba5d04d-7376-4b8c-85a5-712b05167b16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01212-71 (Blood Derived Normal), aliquot CPT0075440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/463946f6-282a-402a-8206-205f29cc3595

The open-access MAF lists 821 somatic variants for this specimen: 550 protein-altering or splice-affecting, 174 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 353, Silent 174, Frame Shift Del 122, Intron 56, Frame Shift Ins 23, Nonsense Mutation 22, 3'UTR 13, 5'UTR 12, RNA 12, In Frame Del 10, Splice Site 9, Splice Region 7.

Variants (750 of 821; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 43/162 reads (27%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DCDC2 | c.529del p.I177Sfs*3 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs904944428; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.2776C>T p.R926* (on ENST00000642864 / NM_001111125.3; = p.R721* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 31/139 reads (22%) | catalogued as rs1057520858; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGA3 | c.2070+1G>A p.X690_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as rs797045048, COSV99144064; ClinVar: pathogenic; called by muse, mutect2
- IYD | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918138, CM081315; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 37/134 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 140/486 reads (29%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 63/245 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 66/153 reads (43%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SACS | c.6172dup p.S2058Ffs*2 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs1214399996; ClinVar: pathogenic; called by mutect2, varscan2
- TTN | c.99022C>T p.R33008* (on ENST00000591111; = p.R25584* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs995029896; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440dup p.A2481Sfs*17 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- ABAT | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285731877; called by muse, mutect2, varscan2
- ABCA2 | c.2776G>T p.A926S (on ENST00000614293; = p.A896S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV55804732; called by muse, mutect2
- ACSBG2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs372123644; called by muse, mutect2, varscan2
- ADAMDEC1 | c.147del p.K49Nfs*32 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs879360738; called by mutect2, pindel, varscan2
- ADGRA2 | c.4012G>A p.V1338I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1265327308; called by muse, mutect2, varscan2
- AGBL3 | c.2474G>T p.R825M | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); catalogued as COSV71379628; called by muse, mutect2, varscan2
- AGRN | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 114/487 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as rs764956867; called by muse, varscan2
- AK5 | c.1620+2C>T p.X540_splice (on ENST00000354567 / NM_174858.3; = p.X514_splice on NM_012093.4) | Splice Site (SNP) | VAF 36/131 reads (27%) | catalogued as rs770347979, COSV100642358; called by muse, mutect2, varscan2
- AKTIP | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1279710988; called by muse, mutect2, varscan2
- AL645922.1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1189108344; called by muse, mutect2, varscan2
- ANAPC5 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1555273362; called by muse, mutect2, varscan2
- ANKRD24 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs377020129; called by mutect2, varscan2
- ANKS1A | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.475); catalogued as rs747927538, COSV100832808; called by muse, mutect2, varscan2
- ANO1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs187484921; called by muse, mutect2, varscan2
- ANPEP | c.2543C>T p.T848I | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs372938510; called by muse, mutect2, varscan2
- ARHGAP11B | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749879540; called by mutect2, varscan2
- ARHGAP33 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.242); catalogued as rs377336785; called by muse, mutect2, varscan2
- ARHGAP39 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs781252700; called by muse, mutect2, varscan2
- ARHGEF7 | c.67del p.T23Pfs*13 | Frame Shift Del (DEL) | VAF 77/250 reads (31%) | catalogued as rs754827718; called by mutect2, pindel, varscan2
- ARVCF | c.1925C>T p.T642M | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs773431238, COSV54265941; called by muse, varscan2
- AS3MT | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1386310668; called by muse, mutect2, varscan2
- ATP1B2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.253); catalogued as rs770644298, COSV51516013; called by muse, mutect2, varscan2
- ATP6V1E1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1191953761, COSV53657009, COSV99494162; called by muse, mutect2, varscan2
- ATRAID | c.832C>T p.R278C (on ENST00000611786; = p.R165C on NM_016085.5) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761451378; called by muse, mutect2, varscan2
- ATXN2L | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1275001677; called by muse, mutect2, varscan2
- B3GNT9 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs765062531; called by muse, mutect2, varscan2
- BARHL1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as rs1388115023, COSV55037727; called by muse, mutect2, varscan2
- BCDIN3D | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777849774, COSV100445613; called by muse, mutect2, varscan2
- BCL11B | c.1883C>T p.A628V (on ENST00000357195 / NM_001282237.2; = p.A557V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs770369592; called by muse, mutect2
- BCL11B | c.1241del p.P414Lfs*61 (on ENST00000357195 / NM_001282237.2; = p.P343Lfs*61 on NM_022898.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 59/175 reads (34%) | catalogued as COSV61736384, COSV61736639; called by mutect2, pindel, varscan2
- BHLHA15 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 147/722 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552021360; called by muse, mutect2, varscan2
- BHLHA9 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs1373273329; called by muse, mutect2, varscan2
- BICRA | c.2935del p.A979Pfs*67 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs756990560, COSV67605323; called by mutect2, pindel, varscan2
- BLVRA | c.353-7G>A | Splice Region (SNP) | VAF 39/143 reads (27%) | catalogued as rs576789900; called by muse, mutect2, varscan2
- BMS1 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1296260140, COSV65735241; called by muse, mutect2, varscan2
- C5orf38 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 82/365 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV57413169; called by muse, mutect2, varscan2
- CACNA1D | c.3046G>A p.G1016S (on ENST00000350061 / NM_001128840.3; = p.G1036S on NM_000720.4) | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs749033002, COSV55471762; called by muse, mutect2, varscan2
- CACNA1H | c.6235G>A p.V2079I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367607849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM2 | c.1169G>A p.R390Q (on ENST00000407528 / NM_001167674.2; = p.R392Q on NM_153184.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67359256; called by muse, mutect2, varscan2
- CAPN8 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.769); catalogued as rs778786142; called by muse, mutect2, varscan2
- CCDC166 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1554617005; called by muse, mutect2, varscan2
- CCDC17 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1232756356, COSV99322350; called by muse, mutect2, varscan2
- CCDC87 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 125/453 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs753437521; called by muse, mutect2, varscan2
- CD163 | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV63135966; called by muse, mutect2, varscan2
- CD163L1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1008192946, COSV58021381; called by muse, mutect2
- CDC42EP4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV59962807; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs1325731082; called by mutect2, varscan2
- CENPJ | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs758150747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP44 | c.773del p.L258* | Frame Shift Del (DEL) | VAF 35/102 reads (34%) | catalogued as COSV56661161; called by mutect2, pindel, varscan2
- CEP97 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779653506; called by muse, mutect2, varscan2
- CFAP44 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55615253; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHEK2 | c.1171T>G p.L391V (on ENST00000382580 / NM_001005735.2; = p.L348V on NM_007194.4) | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60426053; called by muse, mutect2, varscan2
- CHPF | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs1015126095; called by muse, mutect2, varscan2
- CLCNKA | c.1987A>G p.R663G | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV58890458; called by muse, mutect2
- CLUH | c.1703G>A p.R568H (on ENST00000435359; = p.R606H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1447635689; called by muse, mutect2
- CNOT6 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs561133083; called by muse, varscan2
- CNTN1 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs142561108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN5 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201711104; called by muse, mutect2, varscan2
- COL15A1 | c.2828del p.P943Lfs*7 | Frame Shift Del (DEL) | VAF 68/228 reads (30%) | catalogued as rs1449800304; called by mutect2, varscan2
- COL1A1 | c.2444G>C p.G815A | Missense Mutation (SNP) | VAF 118/345 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs66929517, CD077390, CM070709, CM910084; called by muse, mutect2, varscan2
- CRACR2B | c.292del p.V98Wfs*60 | Frame Shift Del (DEL) | VAF 77/272 reads (28%) | catalogued as COSV58990715; called by mutect2, pindel, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 92/386 reads (24%) | catalogued as rs747437399; called by pindel, varscan2
- CYFIP2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV100557739; called by muse, mutect2, varscan2
- CYP21A2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 431/1766 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1185695713, COSV64488380; called by muse, varscan2
- DCLK2 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1358443701; called by muse, varscan2
- DGKG | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs574769788, COSV53964855; called by muse, mutect2, varscan2
- DIAPH2 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs769428501; called by mutect2, varscan2
- DIAPH2 | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1569369481, COSV61298200; called by muse, mutect2, varscan2
- DMPK | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs373602912; called by muse, mutect2, varscan2
- DNMT3B | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 23/625 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1267164985, COSV52416625, COSV52424854; called by muse, mutect2
- DOK2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs777028955; called by muse, mutect2, varscan2
- DRICH1 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs746724033; called by muse, mutect2, varscan2
- DSG1 | c.2569C>T p.R857* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | catalogued as rs756245217, COSV57134384; called by muse, mutect2, varscan2
- DYSF | c.175del p.L59Wfs*92 | Frame Shift Del (DEL) | VAF 60/197 reads (30%) | catalogued as rs1558967217, COSV50342480; called by mutect2, pindel, varscan2
- E2F7 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59743756; called by muse, mutect2, varscan2
- EHD3 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1249384588, COSV59031669; called by muse, mutect2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF1AD | c.344_346del p.N115del | In Frame Del (DEL) | VAF 23/117 reads (20%) | catalogued as rs757432033; called by pindel, varscan2
- EPS8L1 | c.1000C>T p.R334C (on ENST00000201647 / NM_133180.3; = p.R207C on NM_017729.3) | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99137131; called by muse, mutect2, varscan2
- ERCC6 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161878403, COSV63390522; called by muse, mutect2, varscan2
- FAM76A | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1196827299; called by muse, mutect2, varscan2
- FAT1 | c.7430A>G p.Q2477R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV101499131; called by muse, mutect2, varscan2
- FAT4 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 136/384 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as rs781575957; called by muse, mutect2, varscan2
- FBXO10 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs574814970; called by muse, mutect2, varscan2
- FCSK | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1268190695; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs752076602; called by mutect2, pindel
- FLG | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 137/569 reads (24%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.895); catalogued as rs771978807; called by muse, mutect2, varscan2
- FLI1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55643674; called by muse, mutect2, varscan2
- FLVCR1 | c.153_154insC p.A52Rfs*38 | Frame Shift Ins (INS) | VAF 21/56 reads (38%) | catalogued as rs754401455; called by mutect2, pindel*, varscan2
- FNIP1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs761703732; called by muse, mutect2, varscan2
- FOXD4L3 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 318/1157 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs370127483; called by muse, mutect2, varscan2
- FREM2 | c.7534del p.R2512Vfs*38 | Frame Shift Del (DEL) | VAF 41/208 reads (20%) | catalogued as COSV54832051; called by pindel, varscan2
- FUT5 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 279/984 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763909943; called by muse, mutect2, varscan2
- GAL3ST3 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 191/604 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1182464869; called by muse, mutect2, varscan2
- GBP4 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as rs754754322, COSV63253495; called by muse, mutect2, varscan2
- GPD1L | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs764691105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR179 | c.5845del p.E1949Kfs*25 (on ENST00000621958; = p.E1948Kfs*25 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | catalogued as rs937825308; called by mutect2, pindel, varscan2
- GRIN2A | c.3433G>A p.V1145M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs779746293, COSV58025654; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as COSV54945907; called by mutect2, varscan2
- H2AJ | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1280757345; called by muse, mutect2, varscan2
- HDLBP | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 219/680 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs760329761, COSV60491921, COSV60498839; called by muse, mutect2, varscan2
- HECTD2 | c.2256del p.Y753Tfs*7 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as COSV53220620; called by mutect2, pindel, varscan2
- HGS | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs1268324307; called by muse, mutect2, varscan2
- HSPB6 | c.254C>A p.P85Q | Missense Mutation (SNP) | VAF 138/498 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50000617; called by muse, mutect2, varscan2
- HSPH1 | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs747353976; called by muse, mutect2, varscan2
- HUWE1 | c.12020G>A p.R4007H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1556914313; called by muse, mutect2, varscan2
- IGSF1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs780847353, COSV63837170; called by muse, mutect2, varscan2
- IRF4 | c.963del p.D322Tfs*62 | Frame Shift Del (DEL) | VAF 110/416 reads (26%) | catalogued as COSV66705190; called by mutect2, pindel, varscan2
- IRS2 | c.2653G>A p.G885S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1291134080; called by muse, mutect2, varscan2
- ITPK1 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50894001; called by muse, mutect2, varscan2
- ITPR3 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 133/441 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs558328402; called by muse, mutect2, varscan2
- JPH2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 275/1249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65906320; called by muse, mutect2, varscan2
- KCNG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 294/1129 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1386260978, COSV65368626; called by muse, mutect2, varscan2
- KCNH2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 220/712 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs753966347, CM022804, COSV51126692; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs752375544, COSV54318481; called by mutect2, varscan2
- KIAA1614 | c.2689G>A p.V897I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs766645484, COSV62550473; called by muse, mutect2
- KIF15 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs745325493, COSV58163868; called by muse, mutect2
- KIF5A | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs148888970; called by muse, mutect2, varscan2
- KIF7 | c.1640del p.G547Afs*5 | Frame Shift Del (DEL) | VAF 171/528 reads (32%) | catalogued as rs770571299, CX113624; called by mutect2, varscan2
- KISS1R | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 25/685 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as rs1239994909; called by muse, mutect2
- KLHL38 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746593905; called by mutect2, varscan2
- KLK4 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV100133530, COSV60676342; called by muse, mutect2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as COSV51456416; called by pindel, varscan2
- KRT1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs60359468, COSV52867041; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT86 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 374/1516 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs752727601; called by muse, mutect2, varscan2
- LAMA5 | c.4945G>A p.D1649N | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs759144430; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDLR | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1196525889; called by muse, mutect2, varscan2
- LGR6 | c.1238T>C p.I413T (on ENST00000367278 / NM_001017403.1; = p.I361T on NM_021636.3) | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs866775755; called by muse, mutect2
- LINGO1 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as rs1287699778; called by muse, mutect2, varscan2
- LRP1B | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs1180082899; called by muse, mutect2, varscan2
- LRRK1 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs530260600, COSV52613186; called by muse, mutect2, varscan2
- LZTS3 | c.1762C>T p.R588W (on ENST00000329152; = p.R542W on NM_001282533.2) | Missense Mutation (SNP) | VAF 142/452 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99418385; called by muse, mutect2, varscan2
- MAGEA8 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557371039, COSV54064054; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1215313075; called by mutect2, pindel
- MAPK8IP2 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 148/588 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs564527577; called by muse, mutect2, varscan2
- MLKL | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1055108157; called by muse, mutect2, varscan2
- MRGPRG | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 159/461 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934358148; called by muse, mutect2, varscan2
- MROH7 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs555351574; called by muse, mutect2, varscan2
- MUC16 | c.8257G>A p.A2753T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV67469278; called by muse, mutect2, varscan2
- MYBPC2 | c.635del p.P212Rfs*7 | Frame Shift Del (DEL) | VAF 38/147 reads (26%) | catalogued as rs1177894810; called by mutect2, pindel, varscan2
- MYH3 | c.5728C>T p.R1910C | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56866330; called by muse, mutect2, varscan2
- NANS | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 115/441 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs781643145; called by muse, mutect2, varscan2
- NAV1 | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 141/569 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs757338202, COSV55220687; called by muse, mutect2, varscan2
- NCOA1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as rs749644300, COSV56042370; called by muse, mutect2, varscan2
- NDE1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs146749256, COSV104417781; called by muse, mutect2, varscan2
- NDRG1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1269503754; called by muse, mutect2
- NECTIN1 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs201959047, COSV50608374; called by muse, mutect2, varscan2
- NEDD4L | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1334263665; called by muse, mutect2, varscan2
- NELL2 | c.2432A>C p.Q811P | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs367712742; called by muse, mutect2, varscan2
- NOP53 | c.1123A>G p.K375E | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs1172403709; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 41/131 reads (31%) | catalogued as rs781171419; called by mutect2, varscan2
- OR13D1 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1370919364; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 25/101 reads (25%) | catalogued as rs761899382; called by mutect2, varscan2
- OR6B2 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs774717635; called by muse, mutect2, varscan2
- OR7C2 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs201250660, COSV50181428; called by muse, mutect2, varscan2
- OR9A2 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV100628272; called by muse, mutect2, varscan2
- OSTF1 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60547016; called by muse, mutect2, varscan2
- PCCA | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1302507711; called by muse, mutect2, varscan2
- PCDH19 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 42/578 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.805); catalogued as COSV55262786; called by muse, mutect2
- PCDHA10 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 173/735 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.077); catalogued as rs1554150678, COSV100254434, COSV56499029; called by muse, mutect2, varscan2
- PCDHA4 | c.629dup p.L210Ffs*7 | Frame Shift Ins (INS) | VAF 41/140 reads (29%) | catalogued as rs782733777; called by mutect2, varscan2
- PDCD6 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1416762592; called by muse, mutect2, varscan2
- PDZD7 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 173/481 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1018597313; called by muse, mutect2, varscan2
- PELO | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as rs1445878888; called by muse, mutect2, varscan2
- PGLYRP2 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs773492494; called by muse, mutect2, varscan2
- PHF2 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs996570068; called by muse, mutect2, varscan2
- PI4K2A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773047134, COSV65701109; called by muse, mutect2, varscan2
- PIEZO1 | c.5012G>A p.R1671Q | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs987971305, COSV56332453; called by muse, mutect2
- PIK3CG | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1189118505, COSV63248762, COSV63250737; called by muse, mutect2, varscan2
- PKD1 | c.10379C>T p.S3460L (on ENST00000262304 / NM_001009944.3; = p.S3459L on NM_000296.4) | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs373743750; called by muse, mutect2, varscan2
- PLCG1 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.416); catalogued as rs1027449153, COSV99719114; called by muse, mutect2, varscan2
- PLEKHA4 | c.1010del p.P337Rfs*32 | Frame Shift Del (DEL) | VAF 16/212 reads (8%) | catalogued as rs753278744; called by mutect2, pindel
- POLR1C | c.883_885del p.K295del | In Frame Del (DEL) | VAF 70/200 reads (35%) | catalogued as rs875989826; called by pindel, varscan2
- POTEE | c.2241G>A p.M747I | Missense Mutation (SNP) | VAF 101/509 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.106); catalogued as rs760663075; called by muse, mutect2, varscan2
- PPP1R13L | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 162/498 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1473770382; called by muse, mutect2, varscan2
- PRB2 | c.122del p.P41Hfs*390 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs748140635; called by mutect2, pindel, varscan2
- PRDM2 | c.3502G>A p.V1168M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52442345; called by muse, mutect2, varscan2
- PSMA5 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1224820980; called by muse, mutect2, varscan2
- PTBP3 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1293131645; called by muse, varscan2
- PXDN | c.4358del p.P1453Lfs*8 | Frame Shift Del (DEL) | VAF 59/242 reads (24%) | catalogued as rs1432394931, COSV53245090; called by mutect2, pindel, varscan2
- RFT1 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs764531159; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 192/382 reads (50%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNPEPL1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 114/325 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs745836984; called by muse, mutect2, varscan2
- SEC61A2 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53654231; called by muse, mutect2, varscan2
- SETD1A | c.3509_3511del p.F1170del | In Frame Del (DEL) | VAF 73/359 reads (20%) | catalogued as rs1291869496; called by pindel, varscan2
- SHANK3 | c.3392G>A p.R1131H | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.71); catalogued as rs759981448; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 84/252 reads (33%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC1A6 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 177/606 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55671268; called by muse, mutect2, varscan2
- SLC35E4 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368736019; called by muse, mutect2, varscan2
- SLC38A3 | c.1401del p.I469Sfs*13 | Frame Shift Del (DEL) | VAF 104/296 reads (35%) | catalogued as COSV68844080; called by mutect2, pindel, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 35/63 reads (56%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLC6A5 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 78/279 reads (28%) | catalogued as rs142573911, CM119605, COSV100116939; called by muse, mutect2, varscan2
- SLC6A7 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774009545, COSV100046065; called by muse, mutect2, varscan2
- SLCO1B1 | c.1175del p.L392* | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV57008879; called by mutect2, pindel, varscan2
- SLTM | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.599); catalogued as rs1412527063; called by muse, mutect2, varscan2
- SNAPIN | c.392del p.P131Lfs*9 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | catalogued as rs1278771008; called by mutect2, pindel, varscan2
- SOX11 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 54/518 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs749358189, COSV58985452; called by muse, varscan2
- SPATC1L | c.560C>T p.A187V (on ENST00000291672 / NM_001142854.2; = p.A33V on NM_032261.5) | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs769382978, COSV52432612; called by muse, mutect2, varscan2
- SPATS2 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV58918359; called by muse, mutect2, varscan2
- SQSTM1 | c.838_840del p.E280del | In Frame Del (DEL) | VAF 102/458 reads (22%) | catalogued as rs752009611; called by pindel, varscan2
- SRSF11 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1264123991; called by muse, mutect2, varscan2
- SSH2 | c.3943del p.H1315Tfs*10 | Frame Shift Del (DEL) | VAF 57/214 reads (27%) | catalogued as rs763538581; called by mutect2, pindel, varscan2
- STAB1 | c.5814G>C p.R1938S | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV58731726; called by muse, mutect2, varscan2
- STAT1 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV100700027; called by muse, mutect2, varscan2
- STPG1 | c.823G>A p.V275M (on ENST00000337248 / NM_001199013.2; = p.V228M on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528552913; called by muse, mutect2, varscan2
- SYMPK | c.613del p.R205Dfs*49 | Frame Shift Del (DEL) | VAF 41/194 reads (21%) | catalogued as COSV55612338, COSV99842250; called by mutect2, pindel, varscan2
- SYN1 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 132/425 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs745743511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1C | c.1745G>C p.G582A | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58988841; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TCTEX1D4 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs1388898689; called by muse, mutect2
- TEDC1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374888760; called by muse, mutect2, varscan2
- TFDP3 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs765029523, COSV59536978; called by muse, mutect2, varscan2
- TGFBR1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100895303; called by muse, mutect2, varscan2
- TGM1 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 171/599 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs770824119; called by muse, mutect2, varscan2
- TJAP1 | c.1387C>T p.R463* (on ENST00000372445 / NM_001146016.1; = p.R453* on NM_080604.3) | Nonsense Mutation (SNP) | VAF 73/334 reads (22%) | catalogued as rs200207672; called by muse, mutect2, varscan2
- TJP2 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs779601195, CD144210; called by muse, mutect2, varscan2
- TMCC1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs747399032; called by muse, mutect2
- TMEM150B | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 111/442 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1252650138, COSV100442488; called by muse, mutect2, varscan2
- TMEM167A | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV101491865; called by muse, mutect2, varscan2
- TMEM250 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.738); catalogued as rs1484959243, COSV101403446; called by muse, mutect2
- TMEM255B | c.969del p.Y324Tfs*9 | Frame Shift Del (DEL) | VAF 110/354 reads (31%) | catalogued as COSV100944145; called by mutect2, pindel
- TNFRSF1B | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 153/436 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs534114957; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 78/156 reads (50%) | catalogued as rs754233336; called by mutect2, varscan2
- TNRC18 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs768840483, COSV68165834; called by muse, mutect2, varscan2
- TOPAZ1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs373298781; called by muse, mutect2, varscan2
- TRGV2 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs770305161; called by muse, mutect2
- TRMT9B | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs748714155, COSV67947636; called by muse, varscan2
- TSPAN11 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV53816837; called by muse, mutect2
- TSPAN32 | c.543+11del | Splice Region (DEL) | VAF 59/265 reads (22%) | catalogued as rs746788033; called by mutect2, pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.30431A>G p.K10144R (on ENST00000591111; = p.K9217R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | PolyPhen possibly damaging (0.655); catalogued as COSV100594250; called by muse, mutect2, varscan2
- TTN | c.17455C>T p.R5819* (on ENST00000591111; = p.R4892* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 50/199 reads (25%) | catalogued as COSV100607456; called by muse, mutect2, varscan2
- TUBA3D | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.353); catalogued as rs773142096, COSV100342495; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- USP10 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779592460, COSV54748422; called by muse, mutect2, varscan2
- USP19 | c.2044G>A p.V682I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1388876735; called by muse, mutect2, varscan2
- UTS2R | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 258/806 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs199706256, COSV57452633; called by muse, mutect2, varscan2
- VDAC1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1247879450, COSV54737804; called by muse, mutect2, varscan2
- VSX2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 214/759 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs1414724337; called by muse, mutect2, varscan2
- WDR17 | c.1968T>C p.Y656= | Splice Region (SNP) | VAF 14/35 reads (40%) | catalogued as rs200212356, COSV54567628; called by muse, mutect2, varscan2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 80/346 reads (23%) | catalogued as COSV53295493; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 178/644 reads (28%) | catalogued as rs779864368; called by mutect2, varscan2
- ZDHHC15 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.676); catalogued as COSV64900520; called by muse, mutect2
- ZFAT | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100914177; called by muse, mutect2, varscan2
- ZMYM5 | c.1934del p.N645Ifs*56 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs746181263; called by mutect2, varscan2
- ZNF300 | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51032058; called by muse, mutect2, varscan2
- ZNF317 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748398064; called by muse, mutect2, varscan2
- ZNF473 | c.1524G>A p.M508I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54523109; called by muse, mutect2, varscan2
- ZNF516 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 112/536 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs1206513829; called by muse, mutect2, varscan2
- ZNF628 | c.2719G>A p.G907R | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs772139227; called by muse, mutect2, varscan2
- ZNF638 | c.1324A>T p.I442F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52492443; called by muse, varscan2
- ZNF71 | c.305G>C p.C102S | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV60146966; called by muse, mutect2, varscan2
- ZNF729 | c.1263del p.K421Nfs*4 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs1303767176; called by mutect2, pindel, varscan2
- ZNF845 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV72004427; called by muse, mutect2
- ABHD16B | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2
- AC134980.2 | c.701A>T p.N234I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ACOX3 | c.2001G>A p.W667* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- ACSL4 | c.2129del p.G710Afs*9 (on ENST00000340800 / NM_022977.2; = p.G669Afs*9 on NM_004458.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/158 reads (32%) | called by mutect2, pindel, varscan2
- ACSS2 | c.986_987del p.T329Sfs*17 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | called by pindel, varscan2
- ACTL6B | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ADAD2 | c.758T>C p.V253A (on ENST00000315906 / NM_001145400.2; = p.V335A on NM_139174.4) | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAR | c.2885+8C>T | Splice Region (SNP) | VAF 45/151 reads (30%) | called by muse, mutect2, varscan2
- ADARB1 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- ADARB2 | c.79_81dup p.R29dup | In Frame Ins (INS) | VAF 154/491 reads (31%) | called by mutect2, varscan2
- ADGRF2 | c.1358G>A p.G453D (on ENST00000296862 / NM_001368115.2; = p.G385D on NM_153839.7) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADSL | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- AGAP1 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | called by muse, varscan2
- AGRN | c.2996C>G p.A999G | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by mutect2, varscan2
- AHNAK2 | c.5473del p.M1825Cfs*33 | Frame Shift Del (DEL) | VAF 385/1379 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.6350C>A p.P2117Q | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANKRD44 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP2A1 | c.1559del p.P520Qfs*97 | Frame Shift Del (DEL) | VAF 65/252 reads (26%) | called by mutect2, pindel, varscan2
- APBA1 | c.2414T>C p.V805A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARAF | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 47/447 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF15 | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARID1A | c.1650del p.Y551Tfs*68 | Frame Shift Del (DEL) | VAF 171/646 reads (26%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 91/275 reads (33%) | called by mutect2, pindel, varscan2
- ARID1B | c.1263G>T p.Q421H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ARL6IP6 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC8 | c.1507del p.I503* (on ENST00000469044 / NM_001363941.2; = p.I489* on NM_015396.6) | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- ASAH2 | c.1140+1G>A p.X380_splice | Splice Site (SNP) | VAF 68/184 reads (37%) | called by muse, mutect2, varscan2
- ASL | c.447-2A>G p.X149_splice | Splice Site (SNP) | VAF 103/455 reads (23%) | called by muse, mutect2, varscan2
- ATP5MD | c.154del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, varscan2
- ATXN2L | c.1907del p.P636Rfs*19 | Frame Shift Del (DEL) | VAF 48/184 reads (26%) | called by mutect2, pindel, varscan2
- BBS1 | c.1473+1G>A p.X491_splice | Splice Site (SNP) | VAF 99/471 reads (21%) | called by muse, mutect2, varscan2
- BICRA | c.1472C>A p.A491D | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- BMERB1 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- BOD1L1 | c.1052del p.K351Rfs*19 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by mutect2, pindel, varscan2
- BTN1A1 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2
- C3orf70 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CACNA1B | c.6584T>C p.L2195P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CACNG6 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- CASP12 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC122 | c.131del p.N44Tfs*8 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- CCDC136 | c.2647_2648del p.K883Vfs*16 | Frame Shift Del (DEL) | VAF 85/255 reads (33%) | called by mutect2, pindel, varscan2
- CCDC138 | c.852del p.K284Nfs*3 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel
- CCDC178 | c.1931A>C p.E644A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CCDC83 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CD44 | c.900T>A p.D300E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); called by mutect2, varscan2
- CDON | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CEP170 | c.3846A>C p.K1282N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP47 | c.8768del p.F2923Sfs*9 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, pindel, varscan2
- CFAP97 | c.930del p.E313Kfs*15 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- CHD3 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHM | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CIC | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 107/409 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- CLSPN | c.3546G>A p.W1182* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- CNTN6 | c.1638del p.G547Efs*16 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- COL4A5 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- CYP17A1 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 229/518 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DBF4B | c.1064G>T p.R355M | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- DCP1B | c.683T>C p.L228S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDX24 | c.2282T>C p.I761T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- DKK2 | c.320dup p.K108Efs*17 | Frame Shift Ins (INS) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- DNAH9 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, varscan2
- DOC2A | c.112del p.R38Gfs*53 | Frame Shift Del (DEL) | VAF 193/611 reads (32%) | called by mutect2, pindel, varscan2
- DOCK6 | c.2398C>A p.L800M | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EGR3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- EPC1 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- EPHB3 | c.379A>C p.K127Q | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPX | c.786del p.C263Afs*140 | Frame Shift Del (DEL) | VAF 121/414 reads (29%) | called by mutect2, varscan2
- EVL | c.1130C>T p.A377V (on ENST00000402714 / NM_001330221.2; = p.A379V on NM_016337.3) | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- FAM160A1 | c.2320T>C p.Y774H | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- FAM193A | c.3688G>T p.V1230L (on ENST00000324666 / NM_001256666.1; = p.V1189L on NM_003704.3) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- FAM47B | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FANCI | c.3170T>C p.L1057P (on ENST00000310775 / NM_001376911.1; = p.L997P on NM_018193.3) | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FGD5 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FGF10 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLNA | c.6272A>G p.D2091G (on ENST00000369850 / NM_001110556.2; = p.D2083G on NM_001456.3) | Missense Mutation (SNP) | VAF 96/513 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- FLRT1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 122/431 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMN2 | c.4906A>G p.K1636E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- FOXO3 | c.885dup p.T296Hfs*6 | Frame Shift Ins (INS) | VAF 108/350 reads (31%) | called by mutect2, pindel, varscan2
- FUNDC2 | c.302T>G p.F101C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- GALNT10 | c.1748_1749dup p.T584Sfs*63 | Frame Shift Ins (INS) | VAF 29/105 reads (28%) | called by mutect2, varscan2
- GDPD2 | c.875A>G p.H292R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2
- GET4 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GGA1 | c.1376A>G p.Q459R | Missense Mutation (SNP) | VAF 116/446 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- GJA8 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 110/454 reads (24%) | called by muse, mutect2, varscan2
- GOT2 | c.961dup p.L321Pfs*29 | Frame Shift Ins (INS) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- GPR150 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- GPR155 | c.2513C>A p.P838H | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); called by muse, varscan2
- GRAMD1A | c.719+1del | Frame Shift Del (DEL) | VAF 36/151 reads (24%) | called by mutect2, pindel, varscan2
- GRK6 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- GUCY2C | c.1878G>T p.M626I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- GZF1 | c.900_905del p.E305_E306del | In Frame Del (DEL) | VAF 22/72 reads (31%) | called by pindel, varscan2
- HAUS8 | c.652A>G p.M218V | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- HECW2 | c.756del p.F252Lfs*8 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- HHIPL1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 192/540 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- HRH4 | c.826dup p.M276Nfs*19 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- HTATIP2 | c.425del p.L142Yfs*9 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- HTN1 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- IDH3A | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IL17RB | c.762del p.P255Lfs*57 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- INPP5D | c.1093_1095del p.K365del (on ENST00000445964 / NM_001017915.3; = p.K364del on NM_005541.5) | In Frame Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- IPO11 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- IPPK | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- IRF2BPL | c.762dup p.N255Qfs*9 | Frame Shift Ins (INS) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 70/128 reads (55%) | called by mutect2, varscan2
- KBTBD3 | c.1491del p.H498Mfs*4 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- KCNH1 | c.2480del p.G827Afs*48 (on ENST00000271751 / NM_172362.3; = p.G800Afs*48 on NM_002238.4) | Frame Shift Del (DEL) | VAF 97/313 reads (31%) | called by mutect2, pindel, varscan2
- KCP | c.4333del p.L1445Wfs*9 (on ENST00000620378; = p.L1569Wfs*9 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- KDM6B | c.2737G>A p.V913M | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- KMO | c.1421T>C p.V474A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2B | c.6239del p.G2080Afs*11 | Frame Shift Del (DEL) | VAF 59/235 reads (25%) | called by mutect2, pindel, varscan2
- KMT2C | c.13439C>T p.T4480I | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KRTAP13-4 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LDB3 | c.2068T>C p.W690R | Missense Mutation (SNP) | VAF 266/510 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LHX9 | c.998del p.G333Vfs*30 | Frame Shift Del (DEL) | VAF 125/457 reads (27%) | called by mutect2, pindel, varscan2
- LIPI | c.57dup p.Q20Sfs*19 | Frame Shift Ins (INS) | VAF 28/152 reads (18%) | called by mutect2, pindel, varscan2
- LRRC7 | c.3192del p.V1065Sfs*16 (on ENST00000651989 / NM_001370785.2; = p.V1032Sfs*16 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- LRRN3 | c.1823A>G p.N608S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- MAGEC1 | c.1384T>C p.S462P | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAMDC4 | c.2459G>A p.C820Y (on ENST00000445819; = p.C741Y on NM_206920.3) | Missense Mutation (SNP) | VAF 32/934 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAMLD1 | c.1925G>A p.C642Y | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); called by muse, mutect2
- MAP3K10 | c.503del p.P168Hfs*5 | Frame Shift Del (DEL) | VAF 96/308 reads (31%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.4049-1G>A p.X1350_splice | Splice Site (SNP) | VAF 59/161 reads (37%) | called by muse, mutect2, varscan2
- MAP4 | c.2878del p.T960Qfs*35 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, varscan2
- MARVELD1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 150/602 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MCM5 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MED12L | c.3656G>T p.W1219L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- MLST8 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MRC2 | c.4070del p.P1357Rfs*8 | Frame Shift Del (DEL) | VAF 79/234 reads (34%) | called by mutect2, pindel, varscan2
- MRM1 | c.97del p.E33Rfs*3 | Frame Shift Del (DEL) | VAF 65/219 reads (30%) | called by mutect2, pindel, varscan2
- MSL3 | c.385T>A p.L129I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, varscan2
- MTA1 | c.1497dup p.Y500Lfs*43 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- MUC17 | c.7052C>T p.A2351V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5B | c.11386G>A p.A3796T | Missense Mutation (SNP) | VAF 101/565 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUCL3 | c.468del p.K156Nfs*3 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, varscan2
- MUSK | c.2326dup p.Y776Lfs*2 | Frame Shift Ins (INS) | VAF 42/192 reads (22%) | called by mutect2, pindel, varscan2
- MYO18A | c.644del p.P215Hfs*81 | Frame Shift Del (DEL) | VAF 153/480 reads (32%) | called by mutect2, pindel, varscan2
- NAA25 | c.878_880del p.G293del | In Frame Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- NACAD | c.3337G>T p.E1113* | Nonsense Mutation (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- NBEAL1 | c.6945del p.F2315Lfs*2 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- NCAM1 | c.592dup p.E198Gfs*64 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, pindel
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel
- NID2 | c.2654G>A p.G885D | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NOBOX | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 65/271 reads (24%) | called by muse, mutect2, varscan2
- NOXO1 | c.409C>T p.P137S (on ENST00000397280 / NM_172168.3; = p.P131S on NM_144603.4) | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NPAS2 | c.1141-2A>G p.X381_splice | Splice Site (SNP) | VAF 44/104 reads (42%) | called by muse, varscan2
- NPEPL1 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPNT | c.1362_1363del p.S456Gfs*75 | Frame Shift Del (DEL) | VAF 38/215 reads (18%) | called by mutect2, pindel, varscan2
- NPR1 | c.931del p.I311Sfs*16 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- NPTXR | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- NYX | c.1345del p.R449Vfs*111 | Frame Shift Del (DEL) | VAF 84/322 reads (26%) | called by mutect2, pindel, varscan2
- OLFM1 | c.521A>G p.D174G (on ENST00000371793 / NM_001282611.2; = p.D156G on NM_014279.5) | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR2L5 | c.704del p.K235Rfs*12 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- OR8B2 | c.859del p.L287Sfs*5 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, varscan2
- P2RX2 | c.174-1G>T p.X58_splice (on ENST00000343948 / NM_170683.4; = p.X36_splice on NM_012226.5) | Splice Site (SNP) | VAF 85/269 reads (32%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2535del p.I846Sfs*95 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- PCBP2 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, varscan2
- PCIF1 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PFDN5 | c.404_406del p.M135del | In Frame Del (DEL) | VAF 32/98 reads (33%) | called by pindel, varscan2
- PHC2 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, varscan2
- PHKA1 | c.1204T>C p.W402R | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIEZO1 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PKHD1 | c.2752C>A p.P918T | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PKP1 | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- PLCE1 | c.4711A>G p.N1571D | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PLEK2 | c.374del p.P125Rfs*57 | Frame Shift Del (DEL) | VAF 59/238 reads (25%) | called by mutect2, pindel, varscan2
- PLEKHG4B | c.1819C>A p.P607T (on ENST00000283426; = p.P963T on NM_052909.5) | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNB2 | c.2197_2199del p.N733del | In Frame Del (DEL) | VAF 131/438 reads (30%) | called by mutect2, pindel, varscan2
- PNMA2 | c.260del p.G87Vfs*5 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- PNN | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- POLR3B | c.634del p.S212Afs*7 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | called by mutect2, pindel, varscan2
- POMC | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PPP1R36 | c.794G>T p.R265I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP3CB | c.1107del p.V370* | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- PRDM4 | c.2058G>C p.R686S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PRDX2 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 122/568 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PRIMPOL | c.1568del p.L523* | Frame Shift Del (DEL) | VAF 36/137 reads (26%) | called by mutect2, pindel, varscan2
- PRKCZ | c.1009del p.D337Tfs*2 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel
- PRKDC | c.4777G>A p.V1593M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRMT2 | c.1203G>A p.W401* | Nonsense Mutation (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- PRR22 | c.484dup p.D162Gfs*121 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- PSIP1 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PSMD11 | c.1144del p.E382Rfs*4 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- PTPN12 | c.2135dup p.S713Vfs*2 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | called by mutect2, varscan2
- PTPN13 | c.3665G>A p.R1222H (on ENST00000411767 / NM_080683.3; = p.R1203H on NM_006264.3) | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTS | c.234del p.K78Nfs*27 | Frame Shift Del (DEL) | VAF 29/144 reads (20%) | called by mutect2, pindel, varscan2
- QSER1 | c.403C>A p.R135S (on ENST00000399302; = p.R264S on NM_001076786.3) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RAB31 | c.212dup p.L71Ffs*17 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- RARG | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by mutect2, varscan2
- RBM10 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 199/670 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RCSD1 | c.1058del p.P353Lfs*4 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- RFC1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2
- RIN2 | c.1523G>A p.S508N (on ENST00000255006 / NM_001242581.1; = p.S459N on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/425 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- RNASET2 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- RNF220 | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ROCK2 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- RSF1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL10 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 42/558 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- RUSC2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 43/821 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- SAMD15 | c.1454T>C p.L485S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SAMD4B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/138 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SDCCAG8 | c.1419G>T p.K473N | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETX | c.3827A>G p.Q1276R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SIGLEC5 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC22A23 | c.1703+8A>G | Splice Region (SNP) | VAF 156/474 reads (33%) | called by muse, mutect2, varscan2
- SLC23A3 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC38A4 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- SLC39A8 | c.370del p.S124Vfs*13 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- SLC7A2 | c.782C>A p.A261D (on ENST00000494857 / NM_001370338.1; = p.A301D on NM_003046.6) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A9 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 143/666 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLIT3 | c.4401T>A p.C1467* | Nonsense Mutation (SNP) | VAF 25/212 reads (12%) | called by muse, mutect2, varscan2
- SMARCA4 | c.2159T>C p.V720A | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SMPD2 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNRNP200 | c.2393A>G p.E798G | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOD3 | c.721T>C p.*241Rext*31 | Nonstop Mutation (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- SOX3 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 28/854 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2
- SOX6 | c.878del p.P293Lfs*3 | Frame Shift Del (DEL) | VAF 66/253 reads (26%) | called by mutect2, pindel, varscan2
- SPATA31C1 | n.644T>C | Splice Region (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- SPEG | c.54del p.S19Afs*31 | Frame Shift Del (DEL) | VAF 73/304 reads (24%) | called by mutect2, varscan2
- SPRTN | c.1263del p.F421Lfs*7 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.104dup p.G36Rfs*46 | Frame Shift Ins (INS) | VAF 84/272 reads (31%) | called by mutect2, pindel, varscan2
- SRRM1 | c.1417A>G p.M473V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SSU72 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ST3GAL3 | c.936+1del | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | called by mutect2, varscan2
- STXBP1 | c.1322_1324del p.T441del | In Frame Del (DEL) | VAF 164/541 reads (30%) | called by mutect2, pindel, varscan2
- SVEP1 | c.7709C>T p.A2570V | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SYN2 | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SYNGAP1 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 148/644 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SYNJ1 | c.3283A>T p.I1095L | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNJ2 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT6 | c.596A>C p.E199A (on ENST00000610222 / NM_001366225.1; = p.E114A on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, varscan2
- TASOR | c.1686del p.F562Lfs*21 (on ENST00000355628 / NM_001365636.2; = p.F166Lfs*21 on NM_015224.3) | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- TASOR2 | c.5177A>T p.E1726V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TCF7L1 | c.966del p.S323Afs*2 | Frame Shift Del (DEL) | VAF 57/195 reads (29%) | called by mutect2, pindel, varscan2
- TDRD15 | c.1899del p.D634Mfs*6 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- TEKT4 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 147/552 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- TEX55 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.305); called by muse, mutect2
- THADA | c.2550C>G p.Y850* | Nonsense Mutation (SNP) | VAF 47/125 reads (38%) | called by muse, mutect2, varscan2
- THRAP3 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 77/278 reads (28%) | called by muse, mutect2, varscan2
- THSD7B | c.3707A>G p.Q1236R (on ENST00000272643; = p.Q1234R on NM_001316349.2) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TLR5 | c.1494del p.F498Lfs*12 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- TMIGD1 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TOP2A | c.3120G>A p.M1040I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TRAPPC11 | c.1968G>T p.K656N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- TRAV13-1 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV9-1 | c.101A>G p.E34G | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRIP12 | c.273dup p.P92Tfs*8 | Frame Shift Ins (INS) | VAF 37/136 reads (27%) | called by mutect2, varscan2
- TRMT5 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPM6 | c.788T>C p.M263T | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TSC22D1 | c.494T>C p.L165S | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TSHZ3 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, varscan2
- TSR1 | c.2113A>G p.K705E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TTC24 | c.478del p.M160Wfs*13 | Frame Shift Del (DEL) | VAF 98/310 reads (32%) | called by pindel, varscan2
- TTC6 | c.611T>C p.L204P (on ENST00000267368; = p.L1570P on NM_001310135.3) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TTC7A | c.1065+2T>G p.X355_splice | Splice Site (SNP) | VAF 34/199 reads (17%) | called by muse, mutect2, varscan2
- TUT4 | c.955del p.A319Lfs*5 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- UCP2 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- UGT2B11 | c.638del p.N213Ifs*2 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- USP17L15 | c.1568del p.K523Rfs*? | Frame Shift Del (DEL) | VAF 104/717 reads (15%) | called by pindel, varscan2
- USP24 | c.7376T>C p.I2459T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- VPS9D1 | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2
- VWDE | c.885_886insTG p.P296Cfs*4 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- WDR7 | c.3440T>C p.L1147S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WNK4 | c.3474del p.E1159Kfs*60 | Frame Shift Del (DEL) | VAF 102/320 reads (32%) | called by mutect2, pindel, varscan2
- YTHDC1 | c.290del p.N97Mfs*13 | Frame Shift Del (DEL) | VAF 50/166 reads (30%) | called by mutect2, varscan2
- YTHDC2 | c.4066_4067del p.K1356Efs*14 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- YY1AP1 | c.1508C>T p.A503V (on ENST00000295566 / NM_139118.2; = p.A446V on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZADH2 | c.1082del p.N361Tfs*6 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | called by mutect2, varscan2
- ZBTB44 | c.616dup p.Q206Pfs*13 | Frame Shift Ins (INS) | VAF 31/146 reads (21%) | called by mutect2, pindel, varscan2
- ZBTB8B | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP36L2 | c.1120dup p.T374Nfs*100 | Frame Shift Ins (INS) | VAF 161/595 reads (27%) | called by pindel, varscan2
- ZFP62 | c.2372G>T p.G791V (on ENST00000502412 / NM_001377944.1; = p.G758V on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- ZFR2 | c.1604A>G p.Q535R | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ZFYVE16 | c.3608-5T>C | Splice Region (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- ZNF44 | c.766del p.W256Gfs*34 (on ENST00000356109 / NM_001164276.2; = p.W208Gfs*34 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- ZNF518A | c.140del p.N47Mfs*2 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- ZNF579 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ABL1 | c.960C>T p.Y320= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs1458597358; called by muse, mutect2
- AC005324.2 | c.1383G>A p.L461= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- ACOT2 | c.387G>A p.A129= | Silent (SNP) | VAF 171/445 reads (38%) | catalogued as rs1027223417; called by muse, mutect2, varscan2
- ADAMTS18 | c.1389C>A p.P463= | Silent (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- AFF2 | c.2289T>C p.S763= | Silent (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- AJM1 | c.2220G>A p.A740= | Silent (SNP) | VAF 76/279 reads (27%) | catalogued as rs1187487334; called by muse, mutect2, varscan2
- ALCAM | c.1326G>A p.K442= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs1181240700; called by muse, mutect2, varscan2
- ANKRD36 | c.3462T>C p.S1154= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- ANO4 | c.1524A>G p.G508= (on ENST00000392977 / NM_001286615.2; = p.G473= on NM_178826.4) | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- ANO9 | c.897C>T p.Y299= | Silent (SNP) | VAF 119/455 reads (26%) | catalogued as rs750400101; called by muse, mutect2, varscan2
- AP1AR | c.804A>G p.E268= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- APBB1IP | c.1806G>A p.P602= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs1005531139; called by muse, varscan2
- ARHGEF5 | c.636T>C p.P212= | Silent (SNP) | VAF 84/481 reads (17%) | called by muse, mutect2, varscan2
- ARID3A | c.1704C>T p.T568= | Silent (SNP) | VAF 85/328 reads (26%) | catalogued as rs368152991; called by muse, mutect2, varscan2
- ARRDC5 | c.855C>T p.D285= (on ENST00000381781; = p.D271= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/313 reads (31%) | catalogued as rs777901315, COSV67787879; called by muse, mutect2, varscan2
- ASB16 | c.417C>A p.A139= | Silent (SNP) | VAF 200/832 reads (24%) | called by muse, mutect2, varscan2
- ATG9B | c.2094T>C p.R698= | Silent (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- ATIC | c.1182C>T p.V394= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- ATIC | c.1353T>C p.R451= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs745674268, COSV52693537; called by muse, mutect2, varscan2
- ATP2B2 | c.1779C>T p.S593= (on ENST00000352432; = p.S559= on NM_001683.5) | Silent (SNP) | VAF 73/457 reads (16%) | catalogued as rs773331536; called by muse, mutect2, varscan2
- ATP8A2 | c.2220G>A p.R740= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, varscan2
- B3GAT1 | c.699C>T p.N233= | Silent (SNP) | VAF 128/366 reads (35%) | catalogued as rs762279455; called by muse, mutect2, varscan2
- BBS12 | c.603A>G p.K201= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- BICD2 | c.405G>A p.T135= | Silent (SNP) | VAF 59/209 reads (28%) | catalogued as rs746102380, COSV63548808; called by muse, mutect2, varscan2
- BPIFB4 | c.552C>T p.L184= | Silent (SNP) | VAF 130/485 reads (27%) | catalogued as rs745539242; called by muse, mutect2, varscan2
- BRINP3 | c.1269G>A p.T423= | Silent (SNP) | VAF 105/446 reads (24%) | catalogued as COSV66530078, COSV66539699; called by muse, mutect2, varscan2
- BTNL9 | c.1203C>T p.C401= | Silent (SNP) | VAF 86/360 reads (24%) | called by muse, mutect2, varscan2
- C17orf98 | c.54C>T p.D18= | Silent (SNP) | VAF 152/469 reads (32%) | catalogued as rs766483222; called by muse, mutect2, varscan2
- C19orf25 | c.207C>T p.Y69= | Silent (SNP) | VAF 144/432 reads (33%) | catalogued as rs774420526; called by muse, mutect2, varscan2
- C1QC | c.642C>T p.G214= | Silent (SNP) | VAF 52/230 reads (23%) | catalogued as rs778815928; called by muse, mutect2, varscan2
- C2CD3 | c.6606G>A p.E2202= | Silent (SNP) | VAF 88/293 reads (30%) | called by muse, mutect2, varscan2
- CADPS | c.4047C>T p.D1349= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs780719627, COSV51871541; called by muse, mutect2, varscan2
- CCDC181 | c.1107G>A p.K369= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV63157249; called by muse, mutect2, varscan2
- CCDC88B | c.994C>T p.L332= | Silent (SNP) | VAF 81/271 reads (30%) | called by muse, mutect2, varscan2
- CD99L2 | c.333A>G p.P111= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- CDH24 | c.2127G>A p.A709= | Silent (SNP) | VAF 152/487 reads (31%) | called by muse, mutect2, varscan2
- CDH7 | c.1071G>A p.P357= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs138826876, COSV59890298; called by muse, mutect2, varscan2
- CECR2 | c.3069G>A p.P1023= (on ENST00000342247 / NM_001290047.2; = p.P839= on NM_001290046.1) | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as rs777489080; called by muse, mutect2, varscan2
- CENPC | c.1998A>G p.P666= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- CHST12 | c.744C>T p.F248= | Silent (SNP) | VAF 134/683 reads (20%) | catalogued as rs775988101, COSV51674525; called by muse, mutect2, varscan2
- CLASP1 | c.3801C>T p.Y1267= | Silent (SNP) | VAF 26/622 reads (4%) | called by muse, mutect2
- CMSS1 | c.495C>T p.A165= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs750626313, COSV101375605; called by muse, mutect2, varscan2
- CNOT7 | c.768T>C p.C256= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs749697279; called by mutect2, varscan2
- CRAMP1 | c.2373C>T p.S791= | Silent (SNP) | VAF 56/230 reads (24%) | called by muse, mutect2, varscan2
- CSRNP1 | c.1119C>A p.T373= | Silent (SNP) | VAF 135/408 reads (33%) | called by muse, mutect2, varscan2
- CTBP1 | c.402C>T p.C134= | Silent (SNP) | VAF 63/676 reads (9%) | catalogued as COSV52074171; called by muse, mutect2
- CUBN | c.9999G>A p.T3333= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs374885106; called by muse, mutect2, varscan2
- DAW1 | c.525T>C p.G175= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- DHX33 | c.1995C>T p.C665= | Silent (SNP) | VAF 173/608 reads (28%) | catalogued as rs1385484613, COSV56579937; called by muse, mutect2, varscan2
- DLC1 | c.2430T>C p.P810= (on ENST00000276297 / NM_001348081.2; = p.P373= on NM_006094.5) | Silent (SNP) | VAF 12/157 reads (8%) | called by muse, mutect2
- DNMT3A | c.2310G>A p.S770= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs143068605; called by muse, mutect2, varscan2
- DYNC1H1 | c.7263G>A p.T2421= | Silent (SNP) | VAF 149/488 reads (31%) | catalogued as rs201651726, COSV64137401; ClinVar: likely benign; called by muse, mutect2, varscan2
- ECSIT | c.807T>C p.S269= | Silent (SNP) | VAF 133/409 reads (33%) | called by muse, mutect2, varscan2
- EFEMP2 | c.1062G>A p.R354= | Silent (SNP) | VAF 134/459 reads (29%) | called by muse, mutect2, varscan2
- EHMT1 | c.1299C>T p.T433= | Silent (SNP) | VAF 52/268 reads (19%) | catalogued as rs374367377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELF1 | c.1122G>A p.T374= | Silent (SNP) | VAF 51/183 reads (28%) | catalogued as rs765373573, COSV53498007; called by muse, mutect2, varscan2
- ELK1 | c.300G>A p.P100= | Silent (SNP) | VAF 18/390 reads (5%) | catalogued as rs1329006940; called by muse, mutect2
- EPHA3 | c.2406G>A p.T802= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs372376671; called by muse, mutect2, varscan2
- EVX1 | c.1131C>T p.R377= | Silent (SNP) | VAF 34/1102 reads (3%) | called by muse, mutect2
- F11 | c.1773C>T p.G591= | Silent (SNP) | VAF 74/248 reads (30%) | called by muse, mutect2, varscan2
- FAM120A | c.2574G>A p.P858= | Silent (SNP) | VAF 135/488 reads (28%) | catalogued as rs551505031, COSV52910727; called by muse, mutect2, varscan2
- FAM83G | c.249C>T p.G83= | Silent (SNP) | VAF 122/462 reads (26%) | called by muse, mutect2, varscan2
- FCGBP | c.11190C>T p.G3730= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs1311832046; called by muse, mutect2, varscan2
- FCHSD1 | c.699G>A p.L233= | Silent (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- FOLR2 | c.660G>A p.A220= | Silent (SNP) | VAF 37/350 reads (11%) | catalogued as rs1803567, COSV53351520; called by muse, mutect2, varscan2
- FOXL2 | c.210C>T p.S70= | Silent (SNP) | VAF 159/578 reads (28%) | called by muse, mutect2, varscan2
- FRMPD3 | c.1191C>T p.G397= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- FTCD | c.480C>T p.P160= | Silent (SNP) | VAF 39/366 reads (11%) | catalogued as rs759284865, COSV99385639; called by muse, mutect2, varscan2
- FZD6 | c.1671C>A p.S557= | Silent (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- GCN1 | c.4701C>T p.S1567= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs529898136; called by muse, mutect2, varscan2
- GDPD5 | c.912C>T p.T304= | Silent (SNP) | VAF 183/645 reads (28%) | catalogued as COSV61127545; called by muse, mutect2, varscan2
- GJB4 | c.639C>T p.C213= | Silent (SNP) | VAF 107/299 reads (36%) | called by muse, mutect2, varscan2
- HARS2 | c.1026G>A p.L342= | Silent (SNP) | VAF 118/498 reads (24%) | catalogued as rs1233412752; called by muse, mutect2, varscan2
- HECTD4 | c.11616A>G p.A3872= | Silent (SNP) | VAF 89/267 reads (33%) | called by muse, mutect2, varscan2
- HERC2 | c.11679G>A p.L3893= | Silent (SNP) | VAF 55/179 reads (31%) | called by muse, mutect2, varscan2
- HK2 | c.2361G>A p.L787= | Silent (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- HMX3 | c.954C>T p.G318= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as rs755963822; called by muse, mutect2, varscan2
- IGF2R | c.6918C>T p.V2306= | Silent (SNP) | VAF 91/289 reads (31%) | catalogued as rs755390070, COSV100806783, COSV63632741; called by muse, mutect2, varscan2
- IRS1 | c.2994T>A p.R998= | Silent (SNP) | VAF 89/331 reads (27%) | called by muse, mutect2, varscan2
- IRX4 | c.1266C>T p.G422= | Silent (SNP) | VAF 102/300 reads (34%) | catalogued as rs1158300662; called by muse, varscan2
- KATNB1 | c.1674C>T p.T558= | Silent (SNP) | VAF 54/261 reads (21%) | catalogued as rs200775005; called by muse, mutect2, varscan2
- KBTBD11 | c.687G>C p.P229= | Silent (SNP) | VAF 129/289 reads (45%) | called by muse, mutect2, varscan2
- KCNH8 | c.1734G>A p.L578= | Silent (SNP) | VAF 48/151 reads (32%) | called by muse, mutect2, varscan2
- KDM6B | c.4302G>T p.T1434= | Silent (SNP) | VAF 199/814 reads (24%) | catalogued as rs368046343; called by muse, mutect2, varscan2
- KIF7 | c.3342G>A p.Q1114= | Silent (SNP) | VAF 91/307 reads (30%) | called by muse, mutect2, varscan2
- KLHL26 | c.1113G>A p.L371= | Silent (SNP) | VAF 55/277 reads (20%) | catalogued as rs1206259450; called by muse, mutect2, varscan2
- KRTAP10-12 | c.123C>T p.C41= | Silent (SNP) | VAF 188/681 reads (28%) | catalogued as rs782392617; called by muse, mutect2, varscan2
- KRTAP10-5 | c.327A>G p.S109= | Silent (SNP) | VAF 32/852 reads (4%) | called by muse, mutect2
- KRTAP5-1 | c.672G>A p.A224= | Silent (SNP) | VAF 251/770 reads (33%) | catalogued as rs200453575; called by muse, mutect2, varscan2
- LCOR | c.2709C>T p.G903= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs967498716, COSV53716639; called by muse, mutect2, varscan2
- LIMK1 | c.318C>T p.P106= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as rs148361863; called by muse, mutect2, varscan2
- LINGO1 | c.963G>T p.G321= | Silent (SNP) | VAF 114/340 reads (34%) | catalogued as rs769035783; called by muse, mutect2, varscan2
- LLGL2 | c.1173C>T p.H391= | Silent (SNP) | VAF 205/742 reads (28%) | called by muse, mutect2, varscan2
- LRFN2 | c.2100G>C p.G700= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV57825046; called by muse, mutect2, varscan2
- LRFN5 | c.1788C>T p.H596= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as rs770209727, COSV53245814, COSV53262134; called by muse, mutect2, varscan2
- LRRC45 | c.948G>A p.E316= | Silent (SNP) | VAF 60/180 reads (33%) | called by muse, mutect2, varscan2
- MACROH2A2 | c.213C>T p.N71= | Silent (SNP) | VAF 79/201 reads (39%) | called by muse, mutect2, varscan2
- MAP2K7 | c.780C>T p.C260= | Silent (SNP) | VAF 81/295 reads (27%) | catalogued as rs751325660; called by muse, mutect2, varscan2
- MPPED1 | c.111G>A p.R37= | Silent (SNP) | VAF 145/532 reads (27%) | called by muse, mutect2, varscan2
- MTCL1 | c.3270A>G p.P1090= (on ENST00000306329 / NM_001378206.1; = p.P771= on NM_015210.4) | Silent (SNP) | VAF 27/275 reads (10%) | called by muse, mutect2, varscan2
- MTHFD1 | c.2823C>T p.C941= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs1803949; called by muse, mutect2, varscan2
- MTMR14 | c.45C>A p.S15= | Silent (SNP) | VAF 250/869 reads (29%) | called by muse, mutect2, varscan2
- MUC5B | c.12492C>T p.A4164= | Silent (SNP) | VAF 65/436 reads (15%) | catalogued as rs546569767; called by mutect2, varscan2
- MYO18A | c.3834C>T p.N1278= | Silent (SNP) | VAF 94/313 reads (30%) | catalogued as rs200970262; called by muse, mutect2, varscan2
- MZF1 | c.1065C>T p.G355= | Silent (SNP) | VAF 126/507 reads (25%) | catalogued as rs1167038888; called by muse, mutect2, varscan2
- NBPF9 | c.2682T>C p.P894= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as rs781883455; called by muse, mutect2, varscan2
- NCLN | c.1608C>T p.L536= | Silent (SNP) | VAF 58/302 reads (19%) | catalogued as rs780930005, COSV55743172; called by muse, mutect2, varscan2
- NELFB | c.1869C>A p.P623= | Silent (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- NPY1R | c.438A>T p.R146= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- NRG1 | c.1743A>G p.R581= (on ENST00000405005 / NM_013964.5; = p.R586= on NM_013956.5) | Silent (SNP) | VAF 46/171 reads (27%) | called by muse, mutect2, varscan2
- OR12D3 | c.711G>A p.L237= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- OTOL1 | c.1221C>A p.A407= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- PCDH17 | c.1288C>T p.L430= | Silent (SNP) | VAF 154/563 reads (27%) | called by muse, mutect2, varscan2
- PCDHA11 | c.2022G>A p.A674= | Silent (SNP) | VAF 131/386 reads (34%) | catalogued as rs1387416665, COSV56532362; called by muse, mutect2, varscan2
- PCDHA12 | c.1842G>A p.A614= | Silent (SNP) | VAF 27/604 reads (4%) | called by muse, mutect2
- PCF11 | c.3850T>C p.L1284= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1305733321; called by muse, mutect2, varscan2
- PEX1 | c.2034C>T p.H678= | Silent (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- PIK3CD | c.1029G>A p.V343= | Silent (SNP) | VAF 207/912 reads (23%) | catalogued as rs1385002426; called by muse, mutect2, varscan2
- PILRA | c.321C>T p.S107= | Silent (SNP) | VAF 70/283 reads (25%) | catalogued as rs555728760, COSV99546665, COSV99546791; called by muse, mutect2, varscan2
- PKDREJ | c.4255A>C p.R1419= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- PKLR | c.876C>T p.S292= | Silent (SNP) | VAF 289/942 reads (31%) | catalogued as COSV61360579; called by muse, mutect2, varscan2
- PLD2 | c.2208C>T p.C736= | Silent (SNP) | VAF 85/283 reads (30%) | catalogued as rs190680584; called by muse, mutect2, varscan2
- PLXNB1 | c.918C>T p.G306= | Silent (SNP) | VAF 16/440 reads (4%) | called by muse, mutect2
- POT1 | c.732T>G p.L244= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- PPFIA2 | c.696A>G p.S232= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs568996188; called by muse, mutect2, varscan2
- PPP1R3D | c.606G>A p.K202= | Silent (SNP) | VAF 205/683 reads (30%) | called by muse, mutect2, varscan2
- PQBP1 | c.397C>A p.R133= | Silent (SNP) | VAF 146/546 reads (27%) | catalogued as rs201489630; called by muse, varscan2
- PRPF19 | c.639C>T p.H213= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs778898976; called by muse, mutect2, varscan2
- PRRT1 | c.663C>T p.H221= | Silent (SNP) | VAF 142/442 reads (32%) | called by muse, mutect2, varscan2
- PTGS2 | c.756C>T p.V252= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV66572085; called by muse, varscan2
- RET | c.151C>T p.L51= | Silent (SNP) | VAF 299/748 reads (40%) | catalogued as COSV60694287; called by muse, mutect2, varscan2
- RFC3 | c.915A>G p.G305= | Silent (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- RNF135 | c.33C>A p.P11= | Silent (SNP) | VAF 47/1070 reads (4%) | called by muse, mutect2
- S1PR3 | c.549T>C p.P183= | Silent (SNP) | VAF 56/186 reads (30%) | called by muse, mutect2, varscan2
- SBNO2 | c.3657G>A p.Q1219= | Silent (SNP) | VAF 32/320 reads (10%) | catalogued as rs900338992; called by muse, mutect2
- SEPTIN11 | c.93G>A p.L31= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- SERPINB9 | c.420C>T p.T140= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs368042375; called by muse, mutect2, varscan2
- SESN3 | c.207C>A p.S69= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs761042349; called by muse, mutect2, varscan2
- SETX | c.4965G>A p.S1655= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as rs148835280; called by muse, mutect2, varscan2
- SF1 | c.1626G>A p.P542= | Silent (SNP) | VAF 123/561 reads (22%) | catalogued as rs1376845011, COSV57116004; called by muse, mutect2, varscan2
- SH2D3A | c.1449C>T p.G483= | Silent (SNP) | VAF 68/227 reads (30%) | called by muse, mutect2, varscan2
- SHC2 | c.621G>A p.A207= | Silent (SNP) | VAF 87/349 reads (25%) | catalogued as rs750765946; called by muse, mutect2, varscan2
- SIGLEC8 | c.1197G>A p.G399= | Silent (SNP) | VAF 81/289 reads (28%) | catalogued as COSV58474232; called by muse, mutect2, varscan2
- SLC12A2 | c.1653C>T p.N551= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs182493575; called by muse, mutect2, varscan2
- SLC38A3 | c.384C>A p.A128= | Silent (SNP) | VAF 28/544 reads (5%) | called by muse, mutect2
- SMC4 | c.1887C>T p.Y629= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs779018088; called by muse, mutect2, varscan2
- SMCR8 | c.393C>T p.G131= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as rs377235017, COSV100329239; called by muse, mutect2, varscan2
- SOX6 | c.723G>A p.Q241= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as rs374753810; called by muse, mutect2, varscan2
- SSBP3 | c.438C>A p.P146= | Silent (SNP) | VAF 65/265 reads (25%) | catalogued as COSV58886734; called by muse, mutect2, varscan2
- STEAP1B | c.468T>C p.H156= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2
- SYNJ1 | c.2700T>G p.P900= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- TAF4 | c.2337G>A p.T779= | Silent (SNP) | VAF 87/388 reads (22%) | catalogued as rs140240263; called by muse, mutect2, varscan2
- TCEAL7 | c.135C>T p.L45= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV100197124; called by muse, mutect2, varscan2
- TMEM132B | c.45C>T p.T15= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs757107845, COSV54746773; called by muse, mutect2, varscan2
- TMEM175 | c.1134C>T p.V378= | Silent (SNP) | VAF 110/408 reads (27%) | catalogued as COSV99297553; called by muse, mutect2, varscan2
- TNFAIP2 | c.192C>T p.D64= | Silent (SNP) | VAF 131/413 reads (32%) | called by muse, mutect2, varscan2
- TRIO | c.7470C>T p.P2490= | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as rs748883903, COSV59988630; called by muse, mutect2, varscan2
- TTC24 | c.522C>T p.A174= | Silent (SNP) | VAF 56/198 reads (28%) | called by muse, varscan2
- TTC6 | c.492C>G p.R164= | Silent (SNP) | VAF 123/366 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.6489C>T p.H2163= (on ENST00000591111; = p.H2117= on NM_003319.4) | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as rs762045402, COSV59945091; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTYH1 | c.252G>A p.S84= | Silent (SNP) | VAF 59/225 reads (26%) | catalogued as rs768683157, COSV56610835; called by muse, mutect2, varscan2
- UBR4 | c.888T>A p.R296= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- URB2 | c.2655G>A p.Q885= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1160959203; called by muse, mutect2, varscan2
- UROC1 | c.202C>T p.L68= | Silent (SNP) | VAF 106/369 reads (29%) | called by muse, mutect2, varscan2
- WRNIP1 | c.741C>T p.G247= | Silent (SNP) | VAF 83/342 reads (24%) | catalogued as rs757819972; called by muse, mutect2, varscan2
- ZBTB17 | c.1215C>T p.L405= | Silent (SNP) | VAF 122/346 reads (35%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.67C>T p.L23= | Silent (SNP) | VAF 72/233 reads (31%) | catalogued as rs1421667300; called by muse, mutect2, varscan2
- ZFYVE26 | c.2142C>T p.S714= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- ZGLP1 | c.432C>T p.F144= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs574963717; called by muse, mutect2
- ZNF236 | c.3003A>G p.G1001= | Silent (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- ZNF618 | c.300C>T p.C100= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as rs758082547; called by muse, mutect2
- ZNF676 | c.1176T>C p.T392= (on ENST00000650058; = p.T360= on NM_001001411.3) | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, varscan2
- ZNF74 | c.1347C>T p.C449= | Silent (SNP) | VAF 96/320 reads (30%) | catalogued as rs1165930997; called by muse, mutect2, varscan2
- ZRANB2 | c.711G>A p.S237= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs749446252, COSV54671905; called by muse, mutect2, varscan2
- A4GALT | c.*83G>T | 3'UTR (SNP) | VAF 25/612 reads (4%) | called by muse, mutect2
- AC002511.3 | n.362C>T | RNA (SNP) | VAF 35/161 reads (22%) | catalogued as rs1407821665; called by muse, mutect2, varscan2
- AC011840.1 | n.956C>T | RNA (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- ACAD9 | c.150+95C>A | Intron (SNP) | VAF 94/356 reads (26%) | called by muse, mutect2, varscan2
- ACIN1 | c.2298-1533del | Intron (DEL) | VAF 28/94 reads (30%) | catalogued as rs781124581; called by mutect2, varscan2
- ADAR | c.2496+35_2496+38del | Intron (DEL) | VAF 23/54 reads (43%) | called by mutect2, pindel, varscan2
- AKAP17A | c.1152+136A>T | Intron (SNP) | VAF 62/201 reads (31%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850279 del A | 5'Flank (DEL) | VAF 6/43 reads (14%) | catalogued as rs762505968; called by mutect2, pindel, varscan2
- AMDHD2 | c.*3A>G | 3'UTR (SNP) | VAF 100/366 reads (27%) | catalogued as rs1567133667; called by muse, mutect2, varscan2
- ANKRD11 | c.7470+117C>A | Intron (SNP) | VAF 160/576 reads (28%) | called by muse, mutect2, varscan2
- ANKRD11 | c.-59-7496del | Intron (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- AP1AR | c.440+21C>A | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- AP2A1 | c.*221del | 3'UTR (DEL) | VAF 40/158 reads (25%) | called by pindel, varscan2
- APLP2 | c.105+617del | Intron (DEL) | VAF 65/240 reads (27%) | catalogued as rs1228960258; called by mutect2, pindel, varscan2
- BRCA1 | c.*1215A>G | 3'UTR (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- CCNB3 | c.3517-19C>T | Intron (SNP) | VAF 31/124 reads (25%) | catalogued as rs782352431; called by muse, mutect2, varscan2
- CD84 | c.812-44dup | Intron (INS) | VAF 12/47 reads (26%) | catalogued as rs572194057; called by mutect2, varscan2
- CDC42BPB | c.3811+373G>A | Intron (SNP) | VAF 45/176 reads (26%) | called by muse, mutect2, varscan2
- CEP170P1 | n.3902G>A | RNA (SNP) | VAF 12/42 reads (29%) | catalogued as rs749561501; called by muse, mutect2, varscan2
- CLSTN3 | c.2528-1191G>A | Intron (SNP) | VAF 56/320 reads (18%) | called by muse, mutect2, varscan2
- CRTC3 | c.578-20del | Intron (DEL) | VAF 12/45 reads (27%) | catalogued as rs750981842; called by mutect2, pindel, varscan2
- CSGALNACT1 | c.*1513del | 3'UTR (DEL) | VAF 9/26 reads (35%) | catalogued as rs1311950116; called by mutect2, pindel, varscan2
- CSNK1G2 | c.*164del | 3'UTR (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- CTSLP8 | n.765+1del | RNA (DEL) | VAF 16/45 reads (36%) | catalogued as rs34585399; called by mutect2, pindel
- DCAF17 | c.*188del | 3'UTR (DEL) | VAF 20/56 reads (36%) | catalogued as rs746203651; called by mutect2, varscan2
- DNAJC13 | c.6626-950G>A | Intron (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
71 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 71 other) are not listed here.
